Gene-level copy-number profile of tumor specimen AP-QUHC-WB from APOLLO case AP-QUHC, project APOLLO-LUAD (APOLLO1: Proteogenomic characterization of lung adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Invasive mucinous adenocarcinoma; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G3.
Specimen AP-QUHC-WB: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 2f798666-b7fa-4761-bbdc-cbb2e0a2a9c5.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator AP-QUHC-B7 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,231 have no estimate.
https://portal.gdc.cancer.gov/files/cd64dee9-b5bc-40b6-9291-6bb65d2f8158

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 36; copy number 1: 5,537; copy number 2: 40,457; copy number 3: 12,321; copy number 4: 40; copy number 5: 1.

Homozygous deletions (total copy number 0; autosomes only): 13 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:186,286,094–186,555,328, 5 genes (within-gene range 0–1): F11-AS1, AC109517.1, SLC25A5P6, AC018709.1, RNU6-1055P.
- chr4:187,970,273–188,161,157, 8 genes: AC108073.1, ZFP42, TRIML2, AC108073.2, RNU6-173P, TRIML1, AC138781.1, LINC02434.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:150,749,736–150,750,094, 1 gene, copy number 5 (within-gene range 2–5): BET1P1.

Autosomal genes at a single copy (total copy number 1): 3,612. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
